Somatic mutation profile of tumor specimen 0DUIXA from CCDI case PBCLIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DUIXA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 018f19da-af34-4e9d-9e2b-8f0162224494.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d93392-1e01-43c0-8483-e24cbe009057

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/957 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 120/671 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HYDIN | c.6553C>T p.P2185S | Missense Mutation (SNP) | VAF 64/758 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs766357943; called by muse, mutect2
- IL7R | c.1228A>G p.T410A | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.702); catalogued as COSV57408294; called by muse, mutect2, varscan2
- LRRC8D | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 26/908 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs910629309, COSV61578355; called by muse, mutect2
- BAHCC1 | c.1534C>T p.L512= | Silent (SNP) | VAF 51/206 reads (25%) | called by muse, mutect2, varscan2
